Somatic mutation profile of cancer-model specimen HCM-CSHL-0064-C18-85A (3D Organoid; aliquot HCM-CSHL-0064-C18-85A-01D-A768-36), derived from the primary tumor of HCMI case HCM-CSHL-0064-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 75.4 years (27,552 days).
Specimen HCM-CSHL-0064-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 210f09d0-7c12-4d4e-be8c-53a3ffac07ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0064-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0064-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5d6b41b-f83f-4a89-a96d-c0fc302e0b36

The open-access MAF lists 350 somatic variants for this specimen: 226 protein-altering or splice-affecting, 78 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 78, Intron 22, Nonsense Mutation 20, 5'UTR 12, Frame Shift Del 6, RNA 6, Splice Site 6, Splice Region 3, Frame Shift Ins 3, 5'Flank 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 224/225 reads (100%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACER2 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.591); catalogued as COSV61820758; called by muse, mutect2, varscan2
- AGBL1 | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as rs773153038, COSV66858794; called by muse, mutect2, varscan2
- ALK | c.1562T>A p.L521H | Missense Mutation (SNP) | VAF 136/510 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV66568222; called by muse, mutect2, varscan2
- ANKRD24 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs866437534; called by muse, mutect2, varscan2
- APC | c.3404A>T p.Y1135F | Missense Mutation (SNP) | VAF 89/352 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.956); catalogued as CD084033; called by muse, mutect2, varscan2
- APEH | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs758904075; called by muse, mutect2, varscan2
- ASPG | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 196/198 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1170649369; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs569799893; called by muse, mutect2, varscan2
- C2CD2L | c.125C>G p.A42G | Missense Mutation (SNP) | VAF 87/387 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1040454427; called by muse, mutect2, varscan2
- CCER1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs868224869; called by muse, mutect2, varscan2
- CCKBR | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 111/200 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as rs1181500642, COSV100582881; called by muse, mutect2, varscan2
- CEP295 | c.6727G>C p.D2243H | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV57344855; called by muse, mutect2, varscan2
- CHMP4B | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 76/671 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99459768; called by muse, mutect2, varscan2
- CLCN1 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 364/508 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs763760683; called by muse, mutect2, varscan2
- CNGB1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 139/789 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs764107600, COSV51905464; called by muse, mutect2, varscan2
- COL12A1 | c.7869C>A p.N2623K | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201337277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRMP1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs370759908; called by muse, mutect2, varscan2
- DNAJA1 | c.439G>C p.V147L | Missense Mutation (SNP) | VAF 185/311 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV99044021; called by muse, mutect2, varscan2
- DNAJC13 | c.6344G>A p.R2115Q | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.421); catalogued as rs770715465, CM141864, COSV53450154; called by muse, mutect2, varscan2
- DTNB | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs777533811; called by muse, mutect2, varscan2
- ECPAS | c.3916C>T p.L1306F | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV52191015; called by muse, varscan2
- ELAVL2 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 78/455 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.093); catalogued as rs1188175446, COSV99805698; called by muse, mutect2, varscan2
- EPN3 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746697052, COSV52141953; called by muse, mutect2, varscan2
- FAM83B | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 239/413 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1465244268; called by muse, mutect2, varscan2
- FCRL5 | c.2561G>T p.G854V | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV99052721; called by muse, mutect2, varscan2
- FOXO1 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769622051; called by muse, mutect2, varscan2
- GALNT17 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 104/408 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV61149754; called by muse, mutect2, varscan2
- GJD4 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs778114104, COSV58702441; called by muse, mutect2, varscan2
- GOLGA4 | c.6347C>T p.T2116M | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs780800757; called by muse, mutect2, varscan2
- GOLGA6L22 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.18); catalogued as rs1296256160; called by mutect2, varscan2
- GRM6 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 161/318 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51451186; called by muse, mutect2, varscan2
- HLA-F | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 160/290 reads (55%) | catalogued as rs747319246; called by muse, mutect2, varscan2
- IKZF1 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 81/464 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.148); catalogued as COSV100497807, COSV58784077; called by muse, mutect2, varscan2
- INSL3 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs202136873; called by muse, mutect2
- KAT2B | c.306C>T p.A102= | Splice Region (SNP) | VAF 23/182 reads (13%) | catalogued as rs894033666, COSV55431080; called by muse, mutect2, varscan2
- KCNT2 | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99652280; called by muse, mutect2, varscan2
- KLC2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 124/234 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs765203566, COSV100270558; called by muse, mutect2, varscan2
- KLK6 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 195/241 reads (81%) | catalogued as rs377282019, COSV100037783; called by muse, mutect2, varscan2
- KMT2B | c.4847C>T p.A1616V | Missense Mutation (SNP) | VAF 82/414 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55866983, COSV99720244; called by muse, mutect2, varscan2
- LTN1 | c.2467A>T p.I823F | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs1466784065; called by muse, mutect2, varscan2
- MCC | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 288/288 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs764285047; called by muse, mutect2, varscan2
- MROH5 | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 36/312 reads (12%) | catalogued as rs549578686, COSV101436180; called by muse, varscan2
- MROH9 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as rs748891805, COSV63010002; called by muse, mutect2, varscan2
- MS4A18 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs534337923, COSV67517736; called by muse, mutect2, varscan2
- NPIPB15 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 182/2028 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.78); catalogued as rs761593756, COSV70437899; called by muse, mutect2
- OFD1 | c.412+8C>G | Splice Region (SNP) | VAF 62/154 reads (40%) | catalogued as COSV60794453; called by muse, mutect2, varscan2
- OR4D9 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 145/283 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs535085659, COSV61434513; called by muse, varscan2
- OR5D18 | c.545T>C p.F182S | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs1376035809; called by muse, mutect2, varscan2
- OTOF | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 116/476 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs1245016113, COSV55498199, COSV55502880; called by muse, mutect2, varscan2
- PCDHB7 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 296/1251 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.458); catalogued as rs148889209; called by muse, mutect2, varscan2
- PCDHB9 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 299/651 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs782349216; called by muse, mutect2, varscan2
- PDE1C | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs775393302, COSV58502926; called by muse, mutect2, varscan2
- PDILT | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 132/174 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs765889720; called by muse, mutect2, varscan2
- PKHD1 | c.9120C>A p.D3040E | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV61890691; called by muse, mutect2, varscan2
- POM121L12 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 50/345 reads (14%) | catalogued as COSV68694686; called by muse, mutect2, varscan2
- PPP1R13L | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs759404256; called by muse, mutect2, varscan2
- PRAME | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs201064885; called by muse, mutect2, varscan2
- PROCR | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 167/1101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774060495; called by muse, mutect2, varscan2
- PRSS56 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1263692375; called by muse, mutect2, varscan2
- QRICH2 | c.4136G>A p.R1379H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772000651, COSV53154869, COSV53158477; called by muse, mutect2, varscan2
- RAB3D | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs200374153; called by muse, mutect2, varscan2
- RAP1GDS1 | c.544A>T p.I182F (on ENST00000408927 / NM_001100427.2; = p.I183F on NM_021159.5) | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV52786764; called by muse, mutect2, varscan2
- RBM20 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 159/214 reads (74%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs923358109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs370474035; called by muse, mutect2, varscan2
- SLC12A5 | c.2478A>C p.L826F (on ENST00000454036 / NM_001134771.2; = p.L803F on NM_020708.5) | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.359); catalogued as rs1304975707; called by muse, mutect2, varscan2
- SLC15A2 | c.1761+2T>C p.X587_splice | Splice Site (SNP) | VAF 40/226 reads (18%) | catalogued as rs1175374313; called by muse, mutect2, varscan2
- SLC46A3 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 15/440 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV57180752; called by muse, mutect2
- SLC4A3 | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99813087; called by muse, varscan2
- SLC5A11 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 100/633 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1567658010, COSV61744060; called by muse, mutect2, varscan2
- SLC6A5 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 113/479 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV54225086; called by muse, mutect2, varscan2
- SLITRK1 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 58/305 reads (19%) | catalogued as rs1041104860, COSV65674040, COSV65675357; called by muse, mutect2, varscan2
- SYTL3 | c.1034C>T p.P345L (on ENST00000611299 / NM_001242394.1; = p.P277L on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774253415, COSV51908430, COSV99791835; called by muse, mutect2, varscan2
- TBC1D9 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778160381; called by muse, mutect2, varscan2
- TELO2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs1281622827; called by muse, mutect2, varscan2
- TM9SF2 | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225294102; called by muse, mutect2, varscan2
- TMEM132A | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.809); catalogued as rs753135679, COSV50013072; called by muse, mutect2, varscan2
- TSPYL4 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60305651; called by muse, mutect2, varscan2
- TXNDC12 | c.44T>A p.F15Y | Missense Mutation (SNP) | VAF 131/296 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as rs766482803; called by muse, mutect2, varscan2
- UBA7 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757115951; called by muse, mutect2, varscan2
- UGT2B7 | c.1190C>G p.A397G | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV59442867; called by muse, mutect2, varscan2
- UNC80 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.106); catalogued as COSV55904593; called by muse, mutect2, varscan2
- VWCE | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs541004294, COSV57113297; called by muse, mutect2
- VXN | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757732888, COSV59685450; called by muse, mutect2
- WIZ | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765294195; called by muse, mutect2, varscan2
- WRNIP1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 93/352 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.179); catalogued as rs750497757; called by muse, mutect2, varscan2
- ZC3H4 | c.3868G>A p.V1290I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1288669302; called by muse, mutect2, varscan2
- ZFHX2 | c.7028G>A p.G2343D | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV70220418; called by muse, mutect2, varscan2
- ZFP64 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 264/1535 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749217635; called by muse, mutect2, varscan2
- ZNF311 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 187/415 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs1156904558; called by muse, mutect2, varscan2
- ABCA2 | c.4778A>T p.E1593V (on ENST00000614293; = p.E1563V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- AC100868.1 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 70/555 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ACACA | c.5451C>G p.Y1817* | Nonsense Mutation (SNP) | VAF 109/223 reads (49%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.1737G>T p.M579I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ANAPC1 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- ANKFN1 | c.589G>C p.G197R | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- AP3S1 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ARFGEF2 | c.2635G>T p.A879S | Missense Mutation (SNP) | VAF 86/916 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.145); called by muse, mutect2
- ARHGAP15 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ARHGAP32 | c.5508G>A p.M1836I (on ENST00000310343 / NM_001378025.1; = p.M1487I on NM_014715.4) | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF6 | c.1004G>A p.C335Y | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID5A | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 78/136 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ARMC1 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ARNTL2 | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ATP11B | c.2642_2643insG p.Y881* | Nonsense Mutation (INS) | VAF 10/96 reads (10%) | called by mutect2, varscan2
- BASP1 | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- C20orf96 | c.307A>T p.T103S (on ENST00000360321 / NM_153269.3; = p.T102S on NM_080571.1) | Missense Mutation (SNP) | VAF 75/355 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C3orf84 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 93/428 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CC2D2B | c.131A>T p.K44M (on ENST00000646931 / NM_001349008.3; = p.K36M on NM_001130446.3) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CCDC168 | c.13066G>C p.D4356H | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CCDC168 | c.10917T>G p.N3639K | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CCDC91 | c.301T>A p.S101T | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC91 | c.302C>A p.S101* | Nonsense Mutation (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2, varscan2
- CCL23 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CDC14A | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 44/201 reads (22%) | called by muse, mutect2, varscan2
- CEP128 | c.1383C>A p.Y461* | Nonsense Mutation (SNP) | VAF 225/347 reads (65%) | called by muse, mutect2, varscan2
- CFAP94 | c.1743_1753del p.Y581* (on ENST00000320267 / NM_001352064.2; = p.Y587* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (DEL) | VAF 27/202 reads (13%) | called by mutect2, pindel, varscan2
- CMYA5 | c.5572A>T p.R1858* | Nonsense Mutation (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- COL25A1 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- COL6A3 | c.6625A>T p.K2209* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- COPS8 | c.198+1del p.X66_splice | Splice Site (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel*, varscan2
- COX19 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPO | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CTH | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 139/673 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH3 | c.7517A>G p.N2506S | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- DNAH9 | c.4407A>G p.I1469M | Missense Mutation (SNP) | VAF 97/185 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- DNAJB7 | c.881_882insC p.K294Nfs*5 | Frame Shift Ins (INS) | VAF 18/71 reads (25%) | called by mutect2, pindel
- DOCK2 | c.1475C>G p.T492R | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- DOCK8 | c.2752G>T p.E918* | Nonsense Mutation (SNP) | VAF 120/559 reads (21%) | called by muse, mutect2, varscan2
- DPEP2 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DPY19L3 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DSCC1 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DUSP1 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDC3 | c.1192+6C>G | Splice Region (SNP) | VAF 76/200 reads (38%) | called by muse, mutect2, varscan2
- ELMO2 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.024); called by muse, mutect2
- ENAM | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ERBIN | c.2650T>G p.Y884D | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- FAM20B | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- FAM234B | c.1741A>T p.S581C | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FKBP6 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 44/718 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- FNBP4 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 171/373 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FRAS1 | c.8927_8928del p.S2976Ffs*21 | Frame Shift Del (DEL) | VAF 80/186 reads (43%) | called by pindel, varscan2
- FRMD3 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRYL | c.989T>G p.L330* | Nonsense Mutation (SNP) | VAF 92/149 reads (62%) | called by muse, mutect2, varscan2
- GABRA5 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GP6 | c.998A>C p.H333P | Missense Mutation (SNP) | VAF 140/586 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR150 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GSG1L | c.890A>T p.Y297F (on ENST00000447459 / NM_001109763.2; = p.Y142F on NM_144675.2) | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- HIP1 | c.2965G>C p.E989Q | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXD10 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 84/420 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, varscan2
- IDO1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 58/415 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAK2 | c.2816A>G p.D939G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KCNT2 | c.175+2T>A p.X59_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- KIAA1549 | c.4937C>G p.P1646R | Missense Mutation (SNP) | VAF 142/653 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KIF11 | c.585A>G p.I195M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIF13A | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 122/123 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- KIF2B | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 59/310 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LAMB3 | c.2041G>C p.D681H | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LAT2 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCA5 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 74/570 reads (13%) | called by muse, mutect2, varscan2
- LCP2 | c.289A>T p.S97C | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRB1 | c.34A>T p.T12S | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LIPI | c.657A>T p.L219F | Missense Mutation (SNP) | VAF 97/626 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRD1 | c.2282A>C p.K761T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MCOLN1 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MIIP | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MLF2 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MMP12 | c.108C>G p.Y36* | Nonsense Mutation (SNP) | VAF 36/178 reads (20%) | called by muse, mutect2, varscan2
- MRPL3 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH10 | c.3858+1G>A p.X1286_splice | Splice Site (SNP) | VAF 26/57 reads (46%) | called by muse, varscan2
- NARS1 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFKBIL1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 109/665 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NPIPB15 | c.767T>G p.I256R | Missense Mutation (SNP) | VAF 179/2014 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.893); called by muse, mutect2
- OR2T27 | c.393C>G p.H131Q | Missense Mutation (SNP) | VAF 78/507 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR7A17 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OTX1 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAK1IP1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 131/228 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH11X | c.3577A>G p.I1193V | Missense Mutation (SNP) | VAF 904/907 reads (100%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCSK9 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDPR | c.2563C>G p.L855V | Missense Mutation (SNP) | VAF 50/523 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); called by muse, mutect2
- PLA2G7 | c.430T>G p.Y144D | Missense Mutation (SNP) | VAF 253/648 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLG | c.2296T>A p.C766S | Missense Mutation (SNP) | VAF 103/550 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRT3 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PTK2 | c.789+2T>A p.X263_splice | Splice Site (SNP) | VAF 64/565 reads (11%) | called by muse, mutect2, varscan2
- RANBP3 | c.776C>G p.A259G (on ENST00000340578 / NM_007322.3; = p.A254G on NM_003624.3) | Missense Mutation (SNP) | VAF 108/135 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RANBP6 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RBFOX2 | c.510A>C p.Q170H (on ENST00000438146 / NM_001349995.2; = p.Q100H on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RPN2 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 108/1568 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- RRAD | c.191_203del p.G64Afs*65 | Frame Shift Del (DEL) | VAF 36/173 reads (21%) | called by mutect2, pindel, varscan2
- SAMD9L | c.2916A>G p.I972M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SH3D19 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC24A5 | c.584T>A p.V195D | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLIT2 | c.458T>A p.I153K | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- SLIT2 | c.463_464insC p.N155Tfs*13 | Frame Shift Ins (INS) | VAF 31/129 reads (24%) | called by pindel, varscan2
- SPAG16 | c.1262G>A p.W421* | Nonsense Mutation (SNP) | VAF 83/191 reads (43%) | called by muse, mutect2, varscan2
- SPEF2 | c.3598G>C p.D1200H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SREK1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SRM | c.221_224del p.R74Tfs*8 | Frame Shift Del (DEL) | VAF 77/137 reads (56%) | called by mutect2, pindel, varscan2
- STK17A | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STS | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SVOP | c.946del p.T316Qfs*19 | Frame Shift Del (DEL) | VAF 62/259 reads (24%) | called by mutect2, pindel, varscan2
- TAAR2 | c.337C>T p.L113F (on ENST00000367931 / NM_001033080.1; = p.L68F on NM_014626.3) | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBC1D19 | c.1507-1G>A p.X503_splice | Splice Site (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- TESK2 | c.1492_1494del p.P498del | In Frame Del (DEL) | VAF 90/320 reads (28%) | called by pindel, varscan2
- THADA | c.1821T>A p.H607Q | Missense Mutation (SNP) | VAF 98/361 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TMTC1 | c.1249A>T p.S417C (on ENST00000539277 / NM_001193451.2; = p.S309C on NM_175861.3) | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRERF1 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 139/423 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TSHZ3 | c.287A>C p.E96A | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.971); called by muse, varscan2
- TUBGCP2 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 122/171 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBR5 | c.1502A>G p.Q501R | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- USP25 | c.2012C>G p.T671S | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- VEGFC | c.1040G>T p.C347F | Missense Mutation (SNP) | VAF 133/134 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- VPS13A | c.6548T>C p.F2183S | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- VPS13D | c.939G>C p.K313N | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2
- VWA5B2 | c.3149G>C p.S1050T | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VWA8 | c.923T>A p.L308H | Missense Mutation (SNP) | VAF 140/363 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- WDR24 | c.372G>C p.K124N (on ENST00000248142; = p.K62N on NM_032259.4) | Missense Mutation (SNP) | VAF 95/543 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- XCL1 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZDBF2 | c.1437T>G p.H479Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF268 | c.2362del p.A788Lfs*8 | Frame Shift Del (DEL) | VAF 56/244 reads (23%) | called by mutect2, pindel, varscan2
- ZNF320 | c.1435_1436insAG p.S479Kfs*3 | Frame Shift Ins (INS) | VAF 59/259 reads (23%) | called by mutect2, varscan2*
- ZNF320 | c.1433_1434del p.F478* | Frame Shift Del (DEL) | VAF 60/268 reads (22%) | called by mutect2, varscan2*
- ZNF512B | c.1751T>C p.L584P | Missense Mutation (SNP) | VAF 270/563 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNHIT6 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZSWIM1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 74/962 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- ABCA13 | c.7425T>G p.T2475= | Silent (SNP) | VAF 41/212 reads (19%) | called by muse, mutect2, varscan2
- AC008397.2 | c.1455A>C p.R485= | Silent (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- ACTRT2 | c.540C>A p.T180= | Silent (SNP) | VAF 87/261 reads (33%) | catalogued as COSV65759067; called by muse, mutect2, varscan2
- ADAMTS5 | c.136C>A p.R46= | Silent (SNP) | VAF 62/262 reads (24%) | called by muse, mutect2, varscan2
- ANKRD66 | c.258T>G p.G86= | Silent (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- AP2M1 | c.591G>A p.S197= | Silent (SNP) | VAF 79/607 reads (13%) | catalogued as rs771453400, COSV53047759, COSV53048423; called by muse, mutect2, varscan2
- BACH2 | c.1572T>G p.S524= | Silent (SNP) | VAF 69/187 reads (37%) | called by muse, mutect2, varscan2
- BTBD11 | c.1266A>C p.V422= | Silent (SNP) | VAF 37/120 reads (31%) | called by muse, mutect2, varscan2
- CA13 | c.87A>G p.Q29= | Silent (SNP) | VAF 39/274 reads (14%) | called by muse, mutect2, varscan2
- CEP290 | c.4776T>A p.A1592= | Silent (SNP) | VAF 50/180 reads (28%) | called by muse, mutect2, varscan2
- CFAP69 | c.678T>A p.T226= | Silent (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- COL11A1 | c.2391C>T p.D797= | Silent (SNP) | VAF 44/278 reads (16%) | called by muse, varscan2
- COL11A2 | c.243C>T p.P81= | Silent (SNP) | VAF 296/887 reads (33%) | called by muse, mutect2, varscan2
- COL22A1 | c.1632C>T p.D544= | Silent (SNP) | VAF 71/444 reads (16%) | catalogued as rs373172764; called by muse, mutect2, varscan2
- COL24A1 | c.3729A>G p.G1243= | Silent (SNP) | VAF 42/208 reads (20%) | called by muse, mutect2, varscan2
- COL28A1 | c.960C>T p.P320= | Silent (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- COL5A2 | c.2205A>C p.G735= | Silent (SNP) | VAF 104/476 reads (22%) | called by muse, mutect2, varscan2
- CYP1B1 | c.249C>T p.D83= | Silent (SNP) | VAF 138/280 reads (49%) | catalogued as COSV99572680; called by muse, mutect2, varscan2
- DACT3 | c.954C>T p.A318= | Silent (SNP) | VAF 106/140 reads (76%) | called by muse, mutect2, varscan2
- DMD | c.9594T>C p.S3198= | Silent (SNP) | VAF 174/174 reads (100%) | called by muse, mutect2, varscan2
- DNAH1 | c.8550G>A p.Q2850= | Silent (SNP) | VAF 187/377 reads (50%) | called by muse, mutect2, varscan2
- DRC1 | c.1941G>A p.R647= | Silent (SNP) | VAF 69/280 reads (25%) | catalogued as rs761559151; called by muse, mutect2, varscan2
- EGR4 | c.1653G>A p.A551= (on ENST00000545030; = p.A448= on NM_001965.4) | Silent (SNP) | VAF 109/467 reads (23%) | catalogued as COSV71532047; called by muse, mutect2, varscan2
- EMILIN2 | c.1389C>T p.N463= | Silent (SNP) | VAF 173/173 reads (100%) | catalogued as rs1363674860; called by muse, mutect2, varscan2
- ERGIC3 | c.10C>T p.L4= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs780217381; called by muse, mutect2, varscan2
- ESR1 | c.738C>T p.Y246= | Silent (SNP) | VAF 176/401 reads (44%) | catalogued as rs970273955, COSV52782193, COSV99241207; called by muse, mutect2, varscan2
- FOXC2 | c.1149C>T p.A383= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs1379344558; called by muse, mutect2, varscan2
- GPR61 | c.681C>T p.V227= | Silent (SNP) | VAF 121/244 reads (50%) | called by muse, mutect2, varscan2
- HCN1 | c.939T>C p.G313= | Silent (SNP) | VAF 50/266 reads (19%) | catalogued as rs746190871, COSV100299101; called by muse, mutect2, varscan2
- HTR3E | c.936C>T p.F312= (on ENST00000415389 / NM_001256613.1; = p.F327= on NM_182589.2) | Silent (SNP) | VAF 517/723 reads (72%) | catalogued as rs200034444; called by muse, mutect2, varscan2
- IGFBP1 | c.168C>T p.G56= | Silent (SNP) | VAF 322/761 reads (42%) | called by muse, mutect2, varscan2
- IPO8 | c.267C>G p.R89= | Silent (SNP) | VAF 49/324 reads (15%) | called by muse, mutect2, varscan2
- ITGB7 | c.372G>C p.A124= | Silent (SNP) | VAF 47/157 reads (30%) | called by muse, varscan2
- ITPRIPL2 | c.378C>A p.I126= | Silent (SNP) | VAF 92/227 reads (41%) | called by muse, mutect2, varscan2
- KANSL1L | c.1686A>T p.T562= | Silent (SNP) | VAF 84/378 reads (22%) | called by muse, mutect2, varscan2
- KDM3B | c.177G>A p.V59= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs770495938; called by muse, varscan2
- KIF26B | c.2604C>T p.I868= | Silent (SNP) | VAF 108/230 reads (47%) | catalogued as rs375496913; called by muse, mutect2, varscan2
- LRP1B | c.13542T>C p.F4514= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs754357317; called by muse, mutect2, varscan2
- LRP3 | c.1446C>T p.D482= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs200274257; called by muse, mutect2, varscan2
- LSM11 | c.897G>C p.G299= | Silent (SNP) | VAF 76/301 reads (25%) | catalogued as COSV99643901; called by muse, mutect2, varscan2
- MAML1 | c.2817G>A p.G939= | Silent (SNP) | VAF 51/218 reads (23%) | catalogued as rs775764590; called by muse, mutect2, varscan2
- MAPK7 | c.489G>C p.L163= | Silent (SNP) | VAF 71/151 reads (47%) | called by muse, mutect2, varscan2
- MIA2 | c.786T>C p.S262= | Silent (SNP) | VAF 105/162 reads (65%) | called by muse, mutect2, varscan2
- MYLK3 | c.927C>T p.G309= | Silent (SNP) | VAF 43/235 reads (18%) | catalogued as rs752211624; called by muse, mutect2, varscan2
- NCK1 | c.333T>C p.A111= | Silent (SNP) | VAF 57/237 reads (24%) | called by muse, mutect2, varscan2
- NLRP8 | c.1077G>A p.T359= | Silent (SNP) | VAF 121/164 reads (74%) | catalogued as rs1000244011, COSV52587062; called by muse, mutect2, varscan2
- NPBWR1 | c.153T>G p.G51= | Silent (SNP) | VAF 63/520 reads (12%) | called by muse, mutect2, varscan2
- PAXBP1 | c.135T>A p.G45= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV51608328; called by muse, mutect2, varscan2
- PEG10 | c.966G>A p.P322= (on ENST00000482108 / NM_001040152.2; = p.G356S on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/179 reads (25%) | catalogued as COSV101509847; called by muse, mutect2, varscan2
- PEX13 | c.18A>T p.P6= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- PPDPF | c.201C>T p.F67= | Silent (SNP) | VAF 72/950 reads (8%) | called by muse, mutect2
- RELN | c.3462C>A p.L1154= | Silent (SNP) | VAF 421/555 reads (76%) | catalogued as COSV58996490, COSV59040219; called by muse, mutect2, varscan2
- RIF1 | c.5526T>C p.D1842= | Silent (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2
- RNF213 | c.5181G>A p.T1727= | Silent (SNP) | VAF 76/325 reads (23%) | catalogued as rs1043643434, COSV60411763; called by muse, mutect2, varscan2
- RPS6KA2 | c.1317C>T p.T439= | Silent (SNP) | VAF 65/184 reads (35%) | catalogued as rs1336557047, COSV55821006; called by muse, mutect2, varscan2
- SHOC2 | c.507G>A p.K169= | Silent (SNP) | VAF 104/386 reads (27%) | called by muse, varscan2
- SLC1A2 | c.78G>A p.E26= | Silent (SNP) | VAF 74/170 reads (44%) | called by muse, mutect2, varscan2
- SLFN14 | c.2067T>C p.T689= | Silent (SNP) | VAF 122/448 reads (27%) | called by muse, mutect2, varscan2
- SLITRK6 | c.2475T>C p.A825= | Silent (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2
- SMO | c.1416C>T p.Y472= | Silent (SNP) | VAF 49/201 reads (24%) | catalogued as rs766775464, COSV50842459; called by muse, mutect2, varscan2
- SOX17 | c.738G>A p.P246= | Silent (SNP) | VAF 72/333 reads (22%) | catalogued as rs753314063; called by muse, mutect2, varscan2
- STOX2 | c.1284C>T p.N428= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs183419852; called by muse, mutect2, varscan2
- STRN | c.579C>T p.V193= | Silent (SNP) | VAF 82/191 reads (43%) | called by muse, mutect2, varscan2
- TENM4 | c.258A>G p.E86= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1007198084; called by muse, mutect2, varscan2
- TMEM168 | c.987A>G p.V329= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs749060676; called by muse, mutect2, varscan2
- TRIM71 | c.40C>T p.L14= | Silent (SNP) | VAF 63/227 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.7551G>A p.L2517= (on ENST00000591111; = p.L2471= on NM_003319.4) | Silent (SNP) | VAF 72/255 reads (28%) | called by muse, mutect2, varscan2
- U2SURP | c.898T>C p.L300= | Silent (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
- USH2A | c.4389A>G p.L1463= | Silent (SNP) | VAF 123/479 reads (26%) | called by muse, mutect2, varscan2
- VPS13A | c.2673G>A p.L891= | Silent (SNP) | VAF 104/371 reads (28%) | called by muse, mutect2, varscan2
- XDH | c.3624C>A p.T1208= | Silent (SNP) | VAF 94/359 reads (26%) | called by muse, mutect2, varscan2
- XKR4 | c.1440T>G p.A480= | Silent (SNP) | VAF 56/380 reads (15%) | called by muse, mutect2, varscan2
- YEATS2 | c.2817G>A p.S939= | Silent (SNP) | VAF 104/438 reads (24%) | catalogued as rs777936756; called by muse, mutect2, varscan2
- ZBTB8B | c.1317C>A p.P439= | Silent (SNP) | VAF 162/510 reads (32%) | called by muse, mutect2, varscan2
- ZDBF2 | c.597A>T p.P199= | Silent (SNP) | VAF 49/196 reads (25%) | called by muse, mutect2, varscan2
- ZNF469 | c.10749G>C p.A3583= (on ENST00000437464; = p.A3611= on NM_001367624.2) | Silent (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2, varscan2
- ZNF569 | c.1893G>A p.E631= | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- ZNF677 | c.336T>C p.Y112= | Silent (SNP) | VAF 38/172 reads (22%) | called by muse, mutect2, varscan2
- AFG3L2 | c.-4G>A | 5'UTR (SNP) | VAF 154/154 reads (100%) | called by muse, mutect2, varscan2
- AL163540.1 | n.359G>T | RNA (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2, varscan2
- AL353753.1 | n.471A>C | RNA (SNP) | VAF 29/219 reads (13%) | called by muse, mutect2, varscan2
- AMT | c.696+32G>T | Intron (SNP) | VAF 116/542 reads (21%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.708C>A | RNA (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- AVPR2 | chrX:153902712 C>T | 5'Flank (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- BAHCC1 | c.-119C>A | 5'UTR (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- BRCA2 | c.-8A>T | 5'UTR (SNP) | VAF 70/329 reads (21%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3244T>G | Intron (SNP) | VAF 24/48 reads (50%) | catalogued as COSV99635227; called by muse, mutect2, varscan2
- CELF4 | c.658-84C>T | Intron (SNP) | VAF 160/163 reads (98%) | catalogued as COSV100612084; called by muse, mutect2, varscan2
- COL4A1 | c.-18C>T | 5'UTR (SNP) | VAF 78/416 reads (19%) | catalogued as rs1222089552; called by muse, mutect2, varscan2
- CORO6 | c.-173G>C | 5'UTR (SNP) | VAF 78/161 reads (48%) | called by muse, mutect2, varscan2
- DSCAML1 | c.*42G>A | 3'UTR (SNP) | VAF 45/232 reads (19%) | catalogued as rs762695017; called by muse, mutect2, varscan2
- EFCAB14 | c.1074+32A>T | Intron (SNP) | VAF 67/307 reads (22%) | called by muse, mutect2, varscan2
- ERICH1 | c.-5C>A | 5'UTR (SNP) | VAF 35/36 reads (97%) | called by muse, mutect2, varscan2
- GATM | chr15:45378564 G>A | 5'Flank (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- GPX3 | c.87+155C>T | Intron (SNP) | VAF 21/65 reads (32%) | catalogued as rs919485804; called by muse, mutect2, varscan2
- HP | c.5+60A>G | Intron (SNP) | VAF 75/643 reads (12%) | catalogued as rs1452531144, COSV63325746; called by muse, mutect2, varscan2
- HSPA7 | n.395C>T | RNA (SNP) | VAF 172/390 reads (44%) | called by muse, varscan2
- IGF2BP2 | c.240-23942A>T | Intron (SNP) | VAF 46/403 reads (11%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27194G>C | Intron (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- LINC02817 | n.408C>G | RNA (SNP) | VAF 69/300 reads (23%) | called by muse, mutect2, varscan2
- LRP2 | c.13200-41A>T | Intron (SNP) | VAF 76/360 reads (21%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+3658C>T | Intron (SNP) | VAF 162/314 reads (52%) | catalogued as rs1480392453; called by muse, mutect2, varscan2
- MED13L | c.6501-23G>T | Intron (SNP) | VAF 86/319 reads (27%) | called by muse, mutect2, varscan2
- MFN2 | c.817-22G>A | Intron (SNP) | VAF 136/430 reads (32%) | called by muse, varscan2
- MUS81 | c.-49C>T | 5'UTR (SNP) | VAF 75/291 reads (26%) | called by muse, mutect2, varscan2
- NDRG4 | c.37+11176C>A | Intron (SNP) | VAF 23/205 reads (11%) | called by muse, mutect2, varscan2
- NSMF | c.-5C>A | 5'UTR (SNP) | VAF 45/54 reads (83%) | called by muse, mutect2, varscan2
- PHACTR2 | c.14-33921G>C | Intron (SNP) | VAF 57/197 reads (29%) | catalogued as COSV99991280; called by muse, mutect2, varscan2
- PPIA | c.-22G>T | 5'UTR (SNP) | VAF 41/366 reads (11%) | called by muse, mutect2, varscan2
- RFT1 | c.1102+47_1102+49del | Intron (DEL) | VAF 61/290 reads (21%) | called by mutect2, pindel, varscan2
- RN7SL495P | chr15:22611773 T>A | 5'Flank (SNP) | VAF 82/307 reads (27%) | called by muse, mutect2, varscan2
- RPS3 | chr11:75405638 G>A | 3'Flank (SNP) | VAF 46/292 reads (16%) | called by muse, mutect2, varscan2
- S100A11 | c.-22C>G | 5'UTR (SNP) | VAF 45/212 reads (21%) | called by muse, mutect2, varscan2
- SBF1 | c.-141C>T | 5'UTR (SNP) | VAF 24/64 reads (38%) | catalogued as rs1460204952; called by muse, varscan2
- SCARF2 | c.*43C>T | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- SERPINB11 | c.618+37G>T | Intron (SNP) | VAF 84/85 reads (99%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.191C>T | RNA (SNP) | VAF 71/301 reads (24%) | catalogued as rs1175038660; called by muse, mutect2, varscan2
- SSB | c.345+176C>T | Intron (SNP) | VAF 26/83 reads (31%) | catalogued as rs1167392178; called by muse, mutect2, varscan2
- STRA8 | c.420-9T>G | Intron (SNP) | VAF 66/129 reads (51%) | called by muse, mutect2, varscan2
- STX3 | c.-88C>T | 5'UTR (SNP) | VAF 46/184 reads (25%) | called by muse, mutect2, varscan2
- TRIM6 | c.-68+629T>G | Intron (SNP) | VAF 81/183 reads (44%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+1147G>A | Intron (SNP) | VAF 342/433 reads (79%) | called by muse, mutect2, varscan2
- TXNDC9 | c.309-461C>A | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- UMODL1 | c.1900-58G>A | Intron (SNP) | VAF 134/277 reads (48%) | called by muse, mutect2, varscan2
